Gene-level copy-number profile of tumor specimen C3L-02990-08 from CPTAC case C3L-02990, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IB; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 67.1 years (24,520 days).
Specimen C3L-02990-08: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b7248e55-7fc7-49bf-a1c2-6ae8cc375a27.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-02990-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,267 have no estimate.
https://portal.gdc.cancer.gov/files/a7d681e9-c1e6-4d43-9b37-86293d7f4db5

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 566; copy number 2: 10,311; copy number 3: 30,077; copy number 4: 10,548; copy number 5: 3,356; copy number 6: 1,746; copy number 7: 297; copy number 8: 456; copy number 9: 148; copy number 10: 377; copy number 11: 385; copy number 13: 51; copy number 14: 19; copy number 23: 6.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,486,926–49,589,529, 12 genes: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr16:55,760,566–55,793,960, 1 gene: CES1P1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,739 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:112,396,214–149,321,732, 410 genes, copy number 7–13 (broad region; genes not listed).
- chr1:180,230,264–180,909,166, 9 genes, copy number 7: LHX4, ACBD6, VDAC1P4, MIR3121, OVAAL, Y_RNA, XPR1, U6, LINC02816.
- chr1:248,573,801–248,635,091, 5 genes, copy number 9: OR2T34, OR2T10, Y_RNA, AC098483.2, OR2T11.
- chr3:95,654,423–98,472,924, 40 genes, copy number 8–9: MTHFD2P1, AC107304.1, HNRNPKP4, MIR8060, AC107015.1, RNU6-1094P, MTRNR2L12, RPL18AP8, RCC2P5, CDV3P1, EPHA6, AC117470.1, AC110491.1, ARL6, AC110491.3, CRYBG3, AC110491.2, RIOX2, GABRR3, OR5BM1P, OR5AC1, OR5AC2, AC117460.1, OR5AC4P, POU5F1P7, OR5H1, OR5H14, OR5H15, OR5H5P, OR5H3P, OR5H4P, AC117473.1, OR5H7P, OR5H6, OR5H2, OR5H8, OR5K4, OR5K3, UBFD1P1, OR5K1.
- chr3:169,083,499–191,641,237, 395 genes, copy number 7–11 (broad region; genes not listed).
- chr3:196,142,525–198,123,232, 77 genes, copy number 9–11 (broad region; genes not listed).
- chr5:109,448,349–109,885,423, 11 genes, copy number 7: AC010625.1, AC091917.3, AC091917.2, AC091917.1, KRT18P42, MAN2A1-DT, MAN2A1, RN7SKP230, AC008417.1, LINC01848, PGAM5P1.
- chr5:127,143,082–128,659,185, 19 genes, copy number 7 (within-gene range 4–7): MRPS5P3, AC011416.1, SELENOTP2, AC011416.2, MEGF10, AC010424.1, AC010424.2, HNRNPKP1, PRRC1, CTXN3, AC022118.1, CCDC192, CUL1P1, AC068658.1, LINC01184, SLC12A2, KDELC1P1, FBN2, Y_RNA.
- chr5:171,386,656–171,457,626, 4 genes, copy number 9: MIR3912, NPM1, FGF18, AC093246.1.
- chr8:37,717,579–37,909,037, 10 genes, copy number 7: AC138356.3, AC138356.1, ERLIN2, AC138356.2, PLPBP, ADGRA2, BRF2, RAB11FIP1, AC130304.1, RN7SL709P.
- chr8:54,135,241–54,479,963, 10 genes, copy number 7–8: MRPL15, RNU6ATAC32P, AC060764.1, AC044836.1, RNU105C, AC027250.1, RN7SL250P, SOX17, AC091076.1, TRMT112P7.
- chr8:54,522,799–54,523,297, 1 gene, copy number 8: SEC11B.
- chr8:124,260,646–132,675,592, 109 genes, copy number 7–14 (broad region; genes not listed).
- chr12:42,615,221–48,957,487, 157 genes, copy number 10–14 (broad region; genes not listed).
- chr13:50,862,172–51,024,120, 2 genes, copy number 8 (within-gene range 5–8): RNASEH2B-AS1, RNASEH2B.
- chr14:18,645,044–22,919,182, 335 genes, copy number 7–13 (within-gene range 5–13) (broad region; genes not listed).
- chr14:24,809,656–31,302,739, 77 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr14:33,924,227–34,876,459, 21 genes, copy number 8: EGLN3, EGLN3-AS1, AL356806.1, SPTSSA, RPL23AP71, EAPP, AL445363.3, AL445363.1, RNU1-27P, RNU1-28P, AL445363.2, SNX6, RPS19P3, Metazoa_SRP, RNU6-1261P, RPL23AP8, CFL2, RPL12P6, BAZ1A, RNU7-41P, AL121603.2.
- chr16:18,201,501–18,201,956, 1 gene, copy number 7: AC008785.1.
- chr19:13,731,760–14,206,187, 34 genes, copy number 7: CCDC130, MRI1, AC008686.1, C19orf53, ZSWIM4, AC020916.2, RN7SL619P, AC020916.1, MIR24-2, MIR27A, MIR23A, NANOS3, MIR181C, MIR181D, C19orf57, CC2D1A, PODNL1, DCAF15, RFX1, AC022098.4, RLN3, AC022098.2, IL27RA, PALM3, EEF1DP1, MISP3, MIR1199, C19orf67, SAMD1, PRKACA, AC022098.3, ASF1B, AC022098.1, ADGRL1.
- chr19:29,489,775–30,016,612, 12 genes, copy number 14–23 (within-gene range 6–23): AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, CCNE1, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32.

Autosomal genes at a single copy (total copy number 1): 563. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
